Surgical pathology report (de-identified scan), TCGA case TCGA-H7-8502, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-H7-8502-01A (Primary Tumor).

[page 1 of 8]
Operative Procedure:
Bilateral neck dissection, mandible resection.

Specimen Received:

- A: Right perifacial lymph node
- B: Level 1A neck dissection
- C: Right mental nerve
- D: Right masseter margin
- E: Right buccal fat pad margin
- F: Right distal lingual nerve
- G: Right hamulus
- H: Right proximal lingual nerve
- I: Deep soft palate margin
- J: Right composite mandible resection
- K: Additional right lateral pterygoid
- L: Right lateral pterygoid margin
- M: Additional right medial pterygoid
- N: Right parapharyngeal fat margin
- O: Right medial pterygoid margin
- P: Floor of mouth
- Q: Right tongue base
- R: Right hard palate
- S: Right soft palate
- T: Right lateral pharyngeal wall
- U: Right buccal
- V: Right neck dissection 2-4
- W: Right proximal mandible margin
- X: Right distal mandible margin

Final Pathologic Diagnosis:

Mandible composite, right, mandibulectomy: Keratinizing squamous cell carcinoma, moderately differentiated.

Histologic type/grade: Keratinizing squamous cell carcinoma, moderately differentiated

Tumor size: 5.4 cm (greatest dimension)

Depth of invasion: 2.9 cm (greatest dimension)

Lymph-vascular invasion: Identified

Perineural invasion: Identified

Tumor site: Right retromolar trigone

Tumor focality: Unifocal

Margins:

Margins involved by invasive carcinoma

Specify margin, per orientation:

Proximal (posterior) bone margin positive on permanent sections

Margins involved by moderate epithelial dysplasia

[page 2 of 8]
Specify margin, per orientation:

Right hard and soft palate, right lateral pharyngeal wall

Lymph nodes, extranodal extension: Metastatic squamous cell carcinoma
(2/40 positive, maximal dimension 2.0 cm, extranodal extension identified)

Pathologic staging (pTNM):

TNM descriptors: None

Primary tumor: pT4a

Regional lymph nodes: pN2b

Number examined: 40

Number involved: 2 (size of the largest positive lymph node:
2.0 cm)

Distant metastasis: pMX

Additional pathologic findings: None

Specimen: Right mandible

Received: In formalin

Procedure: Mandibulectomy, right

Specimen size: 9.0 x 8.5 x 6.1 cm

Specimen laterality: Right

A. Lymph node, right perifacial, resection:

Three lymph nodes, negative for malignancy (0/3).

B. Lymph node, 1A, neck dissection:

One lymph node, negative for malignancy (0/1).

C. Nerve, right mental, biopsy:

Negative for malignancy.

Frozen section diagnosis confirmed.

D. Masseter, right, biopsy:

Negative for malignancy.

Frozen section diagnosis confirmed.

E. Buccal fat pad, right, biopsy:

Negative for malignancy.

Frozen section diagnosis confirmed.

F. Nerve, right distal lingual, biopsy:

Negative for malignancy.

Frozen section diagnosis confirmed.

G. Hamulus, right, excision:

Negative for malignancy.

H. Nerve, right proximal lingual, biopsy:

[page 3 of 8]
Negative for malignancy.
Frozen section diagnosis confirmed.

- I. Soft palate, deep margin, biopsy:
Negative for malignancy.
Frozen section diagnosis confirmed.
- J. Mandible, right, resection
Squamous cell carcinoma -- see synoptic report above.
Five benign lymph nodes (0/5).
- K. Lateral pterygoid, additional right, biopsy:
Negative for malignancy.
- L. Lateral pterygoid, right margin, biopsy:
Negative for malignancy.
Frozen section diagnosis confirmed.
- M. Medial pterygoid, additional right, biopsy:
Negative for malignancy.
- N. Parapharyngeal fat, right margin, biopsy:
Negative for malignancy.
Frozen section diagnosis confirmed.
- O. Medial pterygoid, right margin, biopsy:
Negative for malignancy.
Frozen section diagnosis confirmed.
- P. Mouth, floor, biopsy:
Negative for malignancy.
Frozen section diagnosis confirmed.
- Q. Tongue, right base, biopsy:
Negative for malignancy.
Frozen section diagnosis confirmed.
- R. Hard palate, right, biopsy:
Moderate epithelial dysplasia, negative for invasion.
Frozen section diagnosis confirmed.
- S. Soft palate, right, biopsy:
Moderate epithelial dysplasia, negative for invasion.
Frozen section diagnosis confirmed.
- T. Pharyngeal wall, right lateral, biopsy:
Moderate epithelial dysplasia, negative for invasion.
Frozen section diagnosis confirmed.

[page 4 of 8]
U. Right buccal biopsy:

Negative for malignancy.

Frozen section diagnosis confirmed.

V. Lymph node, right, neck dissection, 2-4:

Metastatic squamous cell carcinoma (2/30 lymph nodes involved, maximal dimension 2.0 cm, extranodal extension present).

W. Mandible, right proximal margin, biopsy:

Negative for malignancy.

Frozen section diagnosis confirmed.

X. Mandible, right distal margin, biopsy:

Negative for malignancy.

Frozen section diagnosis confirmed.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSC: Right mental nerve:

No tumor in sections examined.

FSD: Right masseter margin:

No tumor in sections examined.

FSE: Right buccal fat margin:

No tumor in sections examined.

F/S TAT: 20 mins.

FSF: Right distal lingual nerve:

No tumor in sections examined.

FSH: Right proximal lingual nerve:

No tumor in sections examined.

FSI: Deep soft palate margin:

No tumor in sections examined.

FSL: Right lateral pterygoid margin:

No tumor in sections examined.

FSN: Right parapharyngeal fat margin:

No tumor in sections examined.

F/S TAT: 30 mins.

FSO: Right medial pterygoid margin:

No tumor in sections examined.

FSP: Floor of mouth:

No tumor in sections examined.

FSQ: Right tongue base:

No tumor in sections examined.

FSR: Right hard palate:

No tumor in sections examined.

FSS: Right soft palate:

[page 5 of 8]
No tumor in sections examined.

F/S TAT: 50 mins.

FST: Right lateral pharyngeal wall:

Focal squamous dysplasia-favor low grade.

FSU: Right buccal:

No tumor in sections examined.

F/S TAT: 50 mins.

FSW: Right proximal mandible margin:

No tumor in sections examined.

FSX: Right distal mandible margin:

No tumor in sections examined.

F/S TAT: 10 mins.

Gross Description:

A. Received in formalin, labeled "right perifacial lymph nodes" are two tan-pink, irregular, lobulated soft tissues, 0.8 x 0.3 x 0.2 cm and 2.3 x 0.9 x 0.2 cm, submitted in toto in one cassette.

B. Received in formalin, labeled "level 1A neck dissection" is a 3.9 x 3.0 x 0.8 cm tan, lobulated irregular fatty tissue. A submandibular gland is not present. Sectioning reveals two tan-pink, rubbery possible lymph nodes, 0.2 cm and 0.4 cm.

Representative sections are submitted as follows:

B1 one whole lymph node bisected;

B2 one whole possible lymph node.

C. Received without fixative labeled "right mental nerve" is a 0.4 x 0.3 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette C.

D. Received without fixative labeled "right masseter margin" is a 1.8 x 0.7 x 0.4 cm tan, irregular soft tissue. A representative section is submitted for frozen section microscopy, now in cassette D1. The remaining tissue is entirely submitted in cassette D2.

E. Received without fixative labeled "right buccal fat pad margin" is a 3.0 x 2.2 x 0.9 cm aggregate of tan, lobulated irregular fatty tissue. Representative sections are submitted for frozen section microscopy, now in cassette E1. Representative sections of the remaining tissue are submitted in cassette E2.

F. Received without fixative labeled "right distal lingual nerve" are three tan, irregular soft tissues, ranging from 0.3 x 0.1 x 0.1 cm to 0.5 x 0.4 x 0.1 cm, submitted in toto for frozen section microscopy, now in cassette F.

[page 6 of 8]
G. Received in formalin, labeled "right hamulus" is a 1.4 x 1.4 x 0.3 cm aggregate of tan, irregular soft tissue admixed with scant bone, submitted in toto in one cassette following decalcification.

H. Received without fixative labeled "right proximal lingual nerve" are four tan, irregular soft tissues, ranging from 0.3 x 0.1 x 0.1 cm to 0.9 x 0.5 x 0.1 cm, submitted in toto for frozen section microscopy, now in cassette H.

I. Received without fixative labeled "deep soft palate margin" is a 0.9 x 0.4 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette I.

J. Received in formalin, labeled "right composite mandible resection including right level 1B dissection" is a 9.0 x 8.5 x 6.1 cm composite resection, which consists of a 6.9 x 6.1 x 1.3 cm partial right posterior mandible, 3.5 x 2.4 x 2.4 cm right partial base of tongue (double suture), 2.0 x 1.2 x 0.9 cm apparent right tonsil, 3.9 x 3.1 x 1.8 cm right submandibular gland, minimal adherent soft palate (single suture) and associated soft tissues. Involving the retromolar trigone is a 5.4 x 4.2 cm tan-pink, irregular well delineated ulcerated mass, which comes to within 0.5 cm from the nearest/soft palate mucosal edge, 0.5 cm from the anterior mucosal edge and 0.6 cm from the nearest tongue mucosal edge. This mass on sectioning is tan, firm, heterogeneous with a total thickness of 2.9 cm, abutting the lateral soft tissue edge and coming to within 1.2 cm from the posterior inked soft tissue edge. The mass appears to involve the tonsil with no definite extension into the submandibular gland. There is focal apparent bony involvement. The uninvolved mucosa is tan-pink and smooth. The uninvolved tonsil on sectioning is tan and homogeneous. The uninvolved submandibular gland is tan and lobulated. A few tan-pink, rubbery lymph nodes are identified adjacent to the submandibular gland, up to 1.9 cm.

Representative sections are submitted as follows:

J1 anterior mandibular margin taken en face, submitted following decalcification;

J2 posterior mandibular margin taken en face, submitted following decalcification;

J3 mass to nearest/posterior palate mucosal edge;

J4 mass to base of tongue mucosal edge;

J5 mass to tonsil;

J6 mass to lateral soft tissue edge;

J7 mass to posterior soft tissue edge;

J8 mass to mandible, submitted following decalcification;

J9 mass to submandibular gland;

J10 whole possible lymph nodes adjacent to submandibular gland;

J11 representative section from one lymph node adjacent to submandibular gland.

K. Received in formalin, labeled "additional right lateral

[page 7 of 8]
pterygoid" is a 2.6 x 2.0 x 1.3 cm tan, irregular ragged soft tissue. Representative sections are submitted in one cassette.

L. Received without fixative labeled "right lateral pterygoid margin" is a 1.4 x 1.4 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette L.

M. Received in formalin, labeled "additional right medial pterygoid" are three tan, irregular soft tissues, ranging from 0.3 x 0.2 x 0.2 cm to 1.5 x 0.9 x 0.4 cm. The specimens are step sectioned and entirely submitted in one cassette.

N. Received without fixative labeled "right parapharyngeal fat margin" is a 1.6 x 1.3 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette N.

O. Received without fixative labeled "right medial pterygoid margin" is a 1.8 x 1.3 x 0.3 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette O.

P. Received without fixative labeled "floor of mouth" is a 2.4 x 0.5 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette P.

Q. Received without fixative labeled "right tongue base" are two tan, irregular soft tissues, 2.5 x 0.6 x 0.2 cm and 3.0 x 0.6 x 0.2 cm, submitted in toto for frozen section microscopy, now in cassette Q.

R. Received without fixative labeled "right hard palate" is a 1.3 x 0.3 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette R.

S. Received without fixative labeled "right soft palate" are three tan, irregular soft tissues ranging from 0.7 x 0.7 x 0.2 cm to 2.3 x 0.3 x 0.2 cm, submitted in toto for frozen section microscopy, now in cassette S.

T. Received without fixative labeled "right lateral pharyngeal wall" are two tan, irregular soft tissues, 0.9 x 0.5 x 0.2 cm and 1.3 x 0.5 x 0.2 cm, submitted in toto for frozen section microscopy, now in cassette T.

U. Received without fixative labeled "right buccal" is a 3.8 x 0.5 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette U.

V. Received in formalin, labeled "right neck dissection level 2-4" is a 12.8 x 4.7 x 3.5 cm tan, lobulated irregular soft tissue with attached single suture designating level 2 and double suture designating level 4. The specimen is divided into levels 2-4. Sectioning reveals multiple

[page 8 of 8]
tan-pink, rubbery to firm lymph nodes up to 3.1 cm.

Representative sections are submitted as follows:

- V1 multiple whole lymph nodes, level 2;
- V2 representative section from one lymph node, level 2;
- V3 representative section from one lymph node, level 2;
- V4 multiple whole lymph nodes, level 3;
- V5 one whole lymph node bisected, level 3;
- V6 whole possible lymph nodes, level 3;
- V7 whole possible lymph nodes, level 3;
- V8 one whole lymph node bisected, level 4;
- V9-10 whole possible lymph nodes, level 4.

W. Received without fixative labeled "right proximal mandible margin" is a 0.3 x 0.3 x 0.2 cm tan, irregular soft tissue with minimal bone. The soft tissue is submitted for frozen section microscopy, now in cassette W. The remaining tissue is entirely submitted in cassette 2 following decalcification.

X. Received without fixative labeled "right distal mandible margin" is a 0.3 x 0.2 x 0.2 cm tan, irregular soft tissue with minimal bone. Representative sections of the soft tissue are submitted for frozen section microscopy, now in cassette X1. The remaining tissue is entirely submitted in cassette X2 following decalcification.

Microscopic Description:

H&E stained sections of tumor reveal islands and cords of cells with squamous differentiation. Multiple areas of keratin pearls are identified throughout the specimen. Please see final diagnosis for further description.

END OF REPORT

Source: NCI Genomic Data Commons file 0ff45f95-3e60-4590-af5d-fcfa89946da6 (TCGA-H7-8502.715C681B-59AA-43B6-9E91-3F688E5C012E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).